Gene-level copy-number profile of tumor specimen HCM-CSHL-0382-C19-01A from HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e2e5662-27d0-4003-8360-d5ec56d3a6b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0382-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/81561072-0404-416f-aacf-584896bb41ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,513; copy number 2: 49,047; copy number 3: 5,013; copy number 4: 1,968; copy number 5: 857.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–2): KRT8P44.
- chr8:7,082,971–7,187,316, 4 genes (within-gene range 0–1): AF238378.1, AF228730.5, AF228730.2, RPS3AP30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 857 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:10,973,336–11,169,623, 1 gene, copy number 5 (within-gene range 4–5): PHF14.
- chr7:11,180,902–41,133,507, 486 genes, copy number 5 (broad region; genes not listed).
- chr7:45,574,140–53,947,804, 93 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–13,996,443, 277 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,513. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
